Gene-level copy-number profile of tumor specimen TCGA-J9-A8CP-01A from TCGA case TCGA-J9-A8CP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,299 days).
Specimen TCGA-J9-A8CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c9192f00-5ea8-484c-ac73-35ffd6fc807c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J9-A8CP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d20f5607-3f47-4d80-b69f-37150aecad61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 7,505; copy number 2: 50,904; copy number 3: 699; copy number 4: 689.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J9-A8CP-01A-11D-A34T-01): tumor purity 0.6, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:92,631,066–94,447,179, 17 genes: AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
